MMRF case MMRF_2522 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e1e7cea3-ed65-426c-88c7-3d4244e0bcc6

Demographics
Sex at birth: female; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.8 years (22,216 days); ISS stage: I; Days to last known disease status: 624 days (1.7 years); Days to last follow up: 624 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.17 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 16.7 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.319 mg/dL.
- Day 92 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 3.02 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 7.04 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 5.14 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 6.49 mmol/L.
- Day 260: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 7.88 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.61 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 7.26 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 9.81 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -27: Weight: 104 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2522_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2522_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
